Somatic mutation profile of tumor specimen TCGA-AY-4071-01A (aliquot TCGA-AY-4071-01A-01W-1073-09) from TCGA case TCGA-AY-4071, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 63.8 years (23,320 days).
Specimen TCGA-AY-4071-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db609123-f217-4dc3-9617-a7c9dd4bbfa2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AY-4071-10A (Blood Derived Normal), aliquot TCGA-AY-4071-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfd14061-c6f2-4b67-99b1-a49f6535686b

The open-access MAF lists 127 somatic variants for this specimen: 97 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 27, Nonsense Mutation 8, Frame Shift Del 5, 5'UTR 1, Frame Shift Ins 1, Splice Region 1, Translation Start Site 1, 3'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 140/244 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); catalogued as rs727504317, CM076269, COSV61068427, COSV61072298; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SGCE | c.397C>T p.R133* (on ENST00000647096; = p.R97* on NM_003919.3) | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as rs121908489, CM012802, COSV56019205; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 49/70 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.5820G>C p.E1940D | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66069117; called by muse, mutect2, varscan2
- ABI3BP | c.1649C>G p.P550R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV52545866; called by muse, mutect2, varscan2
- ADAMTS16 | c.3387C>A p.S1129R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV56994719; called by muse, mutect2
- ADGRL4 | c.887C>A p.A296E | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.826); catalogued as COSV100875476; called by muse, mutect2, varscan2
- ALDH16A1 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs138383674; called by muse, mutect2, varscan2
- APC | c.2493dup p.P832Tfs*12 | Frame Shift Ins (INS) | VAF 24/179 reads (13%) | catalogued as CI000284; called by mutect2, pindel, varscan2
- APC | c.4303del p.R1435Efs*38 | Frame Shift Del (DEL) | VAF 87/248 reads (35%) | catalogued as COSV57334636, COSV57350030, COSV57366976; called by mutect2, pindel, varscan2
- ATP11C | c.672T>A p.F224L | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100557098; called by muse, mutect2
- ATP12A | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 118/295 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs370861260; called by muse, mutect2, varscan2
- ATP6V1E2 | c.26A>G p.K9R | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV60576430; called by muse, mutect2, varscan2
- BRAP | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 5/143 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100553878; called by muse, mutect2
- CAND1 | c.1829A>C p.N610T | Missense Mutation (SNP) | VAF 36/391 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1286214035, COSV73389720; called by muse, mutect2
- CARD11 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs367917190, COSV62754973; called by muse, mutect2, varscan2
- CCDC150 | c.3250A>T p.K1084* | Nonsense Mutation (SNP) | VAF 136/376 reads (36%) | catalogued as COSV55877030; called by muse, mutect2, varscan2
- CCDC40 | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV53902715; called by muse, mutect2, varscan2
- CCPG1 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100196811; called by muse, mutect2, varscan2
- CCPG1 | c.138G>C p.E46D | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100196818; called by muse, mutect2, varscan2
- CDH11 | c.474G>T p.E158D | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99216739; called by muse, mutect2
- CDH9 | c.1088C>G p.P363R | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV50252202, COSV50339420, COSV50368967; called by muse, mutect2, varscan2
- CFAP44 | c.866C>G p.T289S | Missense Mutation (SNP) | VAF 62/406 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV55614384; called by muse, mutect2, varscan2
- CHL1 | c.1659T>A p.S553R (on ENST00000397491 / NM_001253387.1; = p.S569R on NM_006614.4) | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV99849626; called by muse, mutect2
- CNKSR3 | c.464A>C p.K155T | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.583); catalogued as COSV72161866; called by muse, mutect2, varscan2
- CORO2B | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs749693049, COSV55951659; called by muse, mutect2, varscan2
- CTSC | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.237); catalogued as rs370851747, COSV57057812; called by muse, mutect2, varscan2
- DAAM2 | c.1206C>A p.D402E | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99224167; called by muse, mutect2
- DIS3L | c.1040T>A p.V347E (on ENST00000319212 / NM_001143688.3; = p.V264E on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV59913646; called by muse, mutect2, varscan2
- DOCK3 | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs570454630, COSV56539368; called by muse, mutect2, varscan2
- DOP1A | c.3841T>A p.S1281T | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.078); catalogued as rs750514017, COSV52714941; called by muse, mutect2
- DSEL | c.2392A>T p.T798S | Missense Mutation (SNP) | VAF 112/250 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.161); catalogued as COSV100025062; called by muse, varscan2
- ERBB4 | c.497T>A p.I166N | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53564703; called by muse, mutect2, varscan2
- FBN2 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs138046782, COSV52493545; called by muse, mutect2, varscan2
- FGD6 | c.3850G>T p.D1284Y | Missense Mutation (SNP) | VAF 41/58 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59695644; called by muse, mutect2, varscan2
- FIGN | c.1129A>G p.K377E | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV60770035; called by muse, mutect2, varscan2
- FLG | c.10480C>T p.Q3494* | Nonsense Mutation (SNP) | VAF 179/314 reads (57%) | catalogued as COSV64245703; called by muse, mutect2, varscan2
- FREM2 | c.6758T>G p.F2253C | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54846320; called by muse, mutect2
- FRMPD1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 40/414 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63383738; called by muse, mutect2, varscan2
- FSHR | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775127668, COSV58622879; called by muse, mutect2, varscan2
- GABRB2 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs766605015, COSV99195588; called by muse, mutect2
- GANAB | c.356T>C p.L119S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60467381; called by muse, mutect2
- GPKOW | c.1044G>C p.E348D | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV50244368; called by muse, mutect2
- HTR4 | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58800945; called by muse, mutect2, varscan2
- IRX5 | c.1238C>T p.T413M | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58058554, COSV58059382; called by muse, mutect2, varscan2
- KCNA5 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV52909446, COSV99363482; called by muse, mutect2
- KCNH7 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59807300; called by muse, mutect2, varscan2
- KCNIP1 | c.44T>G p.F15C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV66179924; called by muse, mutect2, varscan2
- KIAA0586 | c.4332A>T p.Q1444H (on ENST00000619416 / NM_001244190.2; = p.Q1383H on NM_014749.5) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as COSV54180126; called by muse, mutect2, varscan2
- LRIF1 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 30/458 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV100870768; called by muse, mutect2
- LRP1B | c.9021C>A p.C3007* | Nonsense Mutation (SNP) | VAF 22/141 reads (16%) | catalogued as COSV67255627; called by muse, mutect2, varscan2
- LRP1B | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV101258240, COSV67255631; called by muse, mutect2
- MROH7 | c.1854C>A p.H618Q | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100272657; called by muse, mutect2
- MTA2 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.176); catalogued as rs370573471; called by muse, mutect2, varscan2
- NEK11 | c.356A>T p.K119I | Missense Mutation (SNP) | VAF 93/188 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV63582866; called by muse, mutect2, varscan2
- NPY2R | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368219126, COSV100279353; called by muse, mutect2
- OR2M2 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 365/779 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.047); catalogued as rs1416740090, COSV62899047; called by muse, mutect2, varscan2
- OR7C1 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 112/443 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1384199647, COSV50182932; called by muse, mutect2, varscan2
- PDE4A | c.2407G>A p.V803M (on ENST00000380702 / NM_001111307.2; = p.V564M on NM_006202.3) | Missense Mutation (SNP) | VAF 95/124 reads (77%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.011); catalogued as rs200409316, COSV53360169; called by muse, mutect2, varscan2
- PMM1 | c.757A>G p.I253V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53448667; called by muse, mutect2
- PSMD2 | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1199903844, COSV59530904; called by muse, mutect2, varscan2
- PTPRK | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 6/102 reads (6%) | catalogued as COSV100950117, COSV63902475; called by muse, mutect2
- RASAL2 | c.1040A>G p.D347G | Missense Mutation (SNP) | VAF 67/288 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62719336; called by muse, mutect2, varscan2
- RNF38 | c.570G>A p.Q190= | Splice Region (SNP) | VAF 13/86 reads (15%) | catalogued as COSV52396589; called by muse, mutect2, varscan2
- RTKN2 | c.1423G>C p.D475H | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59523727; called by muse, mutect2, varscan2
- RUSF1 | c.1287G>T p.M429I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57893461; called by muse, mutect2
- SAMD9L | c.4057G>C p.D1353H | Missense Mutation (SNP) | VAF 80/1319 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.568); catalogued as COSV100560150; called by muse, mutect2
- SASH1 | c.3611G>C p.S1204T | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV66564180; called by muse, mutect2
- SEMA3C | c.1283A>T p.K428M | Missense Mutation (SNP) | VAF 10/358 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV99542128; called by muse, mutect2
- SERPINA3 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 102/149 reads (68%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs763528043, COSV67586572; called by muse, mutect2, varscan2
- SLC36A3 | c.886A>G p.I296V | Missense Mutation (SNP) | VAF 69/317 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58857814; called by muse, mutect2, varscan2
- SLC6A2 | c.540G>A p.W180* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | catalogued as COSV54919714; called by muse, mutect2
- SLITRK5 | c.1036T>C p.S346P | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV61524913; called by muse, mutect2, varscan2
- SMARCD2 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs750388563, COSV56741112; called by muse, mutect2, varscan2
- SMC4 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs779373182, COSV61006925; called by muse, mutect2, varscan2
- STX5 | c.597+1G>A p.X199_splice | Splice Site (SNP) | VAF 23/566 reads (4%) | catalogued as COSV99586661; called by muse, mutect2
- TAX1BP1 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs1340986407, COSV55295605; called by muse, mutect2, varscan2
- TENM1 | c.1561G>A p.V521M | Missense Mutation (SNP) | VAF 165/247 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs764454665, COSV64438930; called by muse, mutect2, varscan2
- TNC | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 7/81 reads (9%) | catalogued as COSV100404664; called by muse, mutect2
- TOPORS | c.2488T>C p.S830P | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.36); catalogued as COSV62117810; called by muse, mutect2
- TRHDE | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53857618; called by muse, mutect2, varscan2
- TTN | c.51740C>T p.P17247L (on ENST00000591111; = p.P9823L on NM_003319.4) | Missense Mutation (SNP) | VAF 31/198 reads (16%) | PolyPhen benign (0.121); catalogued as COSV60238048; called by muse, mutect2, varscan2
- TTN | c.32416G>A p.A10806T (on ENST00000591111; = p.A9879T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/269 reads (9%) | PolyPhen benign (0); catalogued as rs200321239; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.17790G>T p.L5930F (on ENST00000591111; = p.L5003F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/225 reads (15%) | PolyPhen benign (0.003); catalogued as COSV60238079, COSV60411298; called by muse, mutect2, varscan2
- VCAM1 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV54120985; called by muse, mutect2, varscan2
- VPS13B | c.10117A>G p.I3373V | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777046028, COSV62152110; called by muse, mutect2, varscan2
- WAPL | c.819A>C p.E273D | Missense Mutation (SNP) | VAF 88/390 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV53938382; called by muse, mutect2, varscan2
- WRN | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV53304632; called by muse, mutect2, varscan2
- ZC3H4 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 119/186 reads (64%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.849); catalogued as rs993928085, COSV99451543; called by muse, mutect2, varscan2
- ZFHX4 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV51481941; called by muse, mutect2, varscan2
- ZIK1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV56738022; called by muse, mutect2, varscan2
- ZNF330 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV99522405; called by muse, mutect2, varscan2
- ZNF804B | c.270A>T p.Q90H | Missense Mutation (SNP) | VAF 76/295 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.088); catalogued as COSV60844156; called by muse, mutect2, varscan2
- ATRNL1 | c.1798del p.S600Lfs*32 | Frame Shift Del (DEL) | VAF 21/162 reads (13%) | called by mutect2, pindel, varscan2
- RNF168 | c.129_132del p.V44Kfs*35 | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | called by mutect2, pindel, varscan2
- TPTE | c.1384del p.I462Yfs*2 (on ENST00000618007 / NM_199261.4; = p.I444Yfs*2 on NM_199259.4) | Frame Shift Del (DEL) | VAF 49/311 reads (16%) | called by mutect2, pindel, varscan2
- UNC5C | c.2391_2392del p.V799Afs*55 | Frame Shift Del (DEL) | VAF 36/155 reads (23%) | called by pindel, varscan2
- ACTA1 | c.162C>G p.S54= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV100796683; called by muse, mutect2, varscan2
- ATRN | c.3561C>T p.D1187= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as rs749521022, COSV53531902, COSV53535068; called by muse, mutect2, varscan2
- BCAN | c.1488C>G p.P496= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV61258541; called by muse, mutect2, varscan2
- CREB3L4 | c.1038T>C p.N346= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV55132911; called by muse, mutect2, varscan2
- CTAGE1 | c.363G>A p.E121= | Silent (SNP) | VAF 53/580 reads (9%) | catalogued as COSV66944187, COSV66945187; called by muse, mutect2
- DCUN1D3 | c.747C>T p.F249= | Silent (SNP) | VAF 57/348 reads (16%) | catalogued as COSV100176642; called by muse, mutect2, varscan2
- F3 | c.543G>A p.K181= | Silent (SNP) | VAF 78/177 reads (44%) | catalogued as COSV61844843, COSV61845355; called by muse, mutect2, varscan2
- GRIA1 | c.1107T>C p.I369= | Silent (SNP) | VAF 76/166 reads (46%) | catalogued as COSV53616488; called by muse, mutect2, varscan2
- GRIA1 | c.2397C>T p.S799= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs140534681; called by muse, mutect2, varscan2
- GSPT2 | c.462A>G p.K154= | Silent (SNP) | VAF 19/28 reads (68%) | catalogued as COSV61214798; called by muse, mutect2, varscan2
- ITIH5 | c.525C>T p.S175= | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as rs755556933, COSV56910885; called by muse, mutect2, varscan2
- KAT6B | c.2790G>A p.A930= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as rs765834987, COSV54744481; called by muse, mutect2, varscan2
- KIAA1109 | c.6297A>G p.E2099= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV99145313; called by muse, mutect2, varscan2
- LDHC | c.798T>C p.N266= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as COSV55005339; called by muse, mutect2, varscan2
- LUM | c.508C>A p.R170= | Silent (SNP) | VAF 58/271 reads (21%) | catalogued as COSV57127642, COSV57128855; called by muse, mutect2, varscan2
- MUC6 | c.2052G>A p.L684= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV70146837; called by muse, mutect2
- MYH6 | c.1134C>T p.G378= | Silent (SNP) | VAF 24/33 reads (73%) | catalogued as COSV62452934, COSV62453102; called by muse, mutect2, varscan2
- NCOA2 | c.1110A>G p.L370= | Silent (SNP) | VAF 54/289 reads (19%) | catalogued as COSV71764592; called by muse, mutect2, varscan2
- PCDH15 | c.4893G>T p.L1631= (on ENST00000644397 / NM_001354429.2; = p.L1573= on NM_001142771.2) | Silent (SNP) | VAF 83/368 reads (23%) | catalogued as COSV64690114; called by muse, mutect2, varscan2
- PDGFD | c.834G>A p.S278= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs564284731, COSV56387980; called by muse, mutect2, varscan2
- POLK | c.639T>C p.N213= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV54038009; called by muse, mutect2, varscan2
- SLC35F1 | c.798T>C p.A266= | Silent (SNP) | VAF 152/266 reads (57%) | catalogued as COSV64506760; called by muse, varscan2
- SNTA1 | c.1443G>A p.S481= | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as rs530204062, COSV54130151; called by muse, mutect2, varscan2
- STAC | c.615C>T p.F205= | Silent (SNP) | VAF 56/267 reads (21%) | catalogued as rs752252190, COSV56210826, COSV99830682; called by muse, mutect2, varscan2
- SYNE1 | c.25278C>T p.A8426= (on ENST00000367255 / NM_182961.4; = p.A8378= on NM_033071.3) | Silent (SNP) | VAF 22/260 reads (8%) | catalogued as COSV55056446; called by muse, mutect2
- ZNF329 | c.1014C>G p.T338= | Silent (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- ZNFX1 | c.198G>A p.R66= | Silent (SNP) | VAF 34/384 reads (9%) | catalogued as rs1412053996, COSV65577808; called by muse, mutect2
- DUSP13 | c.*507C>G | 3'UTR (SNP) | VAF 39/96 reads (41%) | catalogued as COSV57815631; called by muse, mutect2, varscan2
- KNOP1P1 | n.356G>A | RNA (SNP) | VAF 19/183 reads (10%) | catalogued as rs755839231; called by muse, mutect2, varscan2
- OSBPL6 | c.-1G>A | 5'UTR (SNP) | VAF 78/132 reads (59%) | catalogued as rs371130039; called by muse, mutect2, varscan2
